Somatic mutation profile of tumor specimen MP2PRT-PAPMVR-TMP1-A (aliquot MP2PRT-PAPMVR-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPMVR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (702 days).
Specimen MP2PRT-PAPMVR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b77ac2f-472e-410c-afb2-1eb85b36e9c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPMVR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPMVR-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c44f66dc-73b8-475a-826f-ddeb2b5f0933

The open-access MAF lists 48 somatic variants for this specimen: 29 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 18, Splice Region 3, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 73/333 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS8 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 89/502 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs758545232; called by muse, mutect2, varscan2
- ANO3 | c.693G>A p.R231= | Splice Region (SNP) | VAF 57/282 reads (20%) | catalogued as rs1024348703, COSV56808297; called by muse, mutect2, varscan2
- CPS1 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865881540, COSV51827465; called by muse, mutect2, varscan2
- DNAH17 | c.4584G>A p.K1528= | Splice Region (SNP) | VAF 104/454 reads (23%) | catalogued as COSV101103954; called by muse, mutect2, varscan2
- DZIP1L | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs143605646; called by muse, mutect2, varscan2
- GLI1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 91/459 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV57359558; called by muse, mutect2, varscan2
- GRM1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 102/447 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as COSV51136481, COSV51378248; called by muse, mutect2, varscan2
- ITGAX | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1485837046; called by muse, mutect2, varscan2
- KIF21A | c.3884G>A p.G1295E (on ENST00000361418 / NM_001378440.1; = p.G1282E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as rs1565724787; called by muse, mutect2, varscan2
- MUC4 | c.6052C>T p.P2018S | Missense Mutation (SNP) | VAF 115/1062 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.65); catalogued as rs758036933; called by muse, mutect2
- OR51I1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 84/401 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV66507955; called by muse, mutect2, varscan2
- OVCH1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1243703809; called by muse, mutect2, varscan2
- PLCL1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 84/314 reads (27%) | catalogued as COSV70874602; called by muse, mutect2, varscan2
- PLS1 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61833764; called by muse, mutect2, varscan2
- TEX15 | c.5195G>A p.G1732E (on ENST00000256246; = p.G2115E on NM_001350162.2) | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as rs867773375; called by muse, mutect2, varscan2
- WDR31 | c.598G>A p.E200K (on ENST00000374193 / NM_001006615.3; = p.E199K on NM_145241.5) | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as rs758039117, COSV59145334; called by muse, mutect2, varscan2
- WSCD1 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 92/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1012317416; called by muse, mutect2, varscan2
- ATF7IP | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CNOT1 | c.3828G>A p.K1276= | Splice Region (SNP) | VAF 39/264 reads (15%) | called by muse, mutect2, varscan2
- DSP | c.3196C>T p.Q1066* | Nonsense Mutation (SNP) | VAF 61/348 reads (18%) | called by muse, mutect2, varscan2
- ETS2 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 66/368 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.186); called by muse, mutect2
- FLRT2 | c.1762T>C p.Y588H | Missense Mutation (SNP) | VAF 77/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LONRF1 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PPARGC1B | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAMP2 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 86/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SDK1 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBA8 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 104/477 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCL11B | c.1107G>A p.E369= (on ENST00000357195 / NM_001282237.2; = p.E298= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 138/595 reads (23%) | called by muse, mutect2, varscan2
- CDH11 | c.1248G>A p.P416= | Silent (SNP) | VAF 57/252 reads (23%) | catalogued as rs139869458; called by muse, mutect2, varscan2
- CHD5 | c.1893C>T p.I631= | Silent (SNP) | VAF 96/466 reads (21%) | catalogued as rs1557551425; called by muse, mutect2, varscan2
- DIS3 | c.1326G>A p.Q442= | Silent (SNP) | VAF 66/345 reads (19%) | called by muse, mutect2, varscan2
- EMB | c.948C>T p.V316= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- ESS2 | c.1167C>T p.G389= | Silent (SNP) | VAF 77/385 reads (20%) | called by muse, mutect2, varscan2
- FREM3 | c.4587C>T p.F1529= | Silent (SNP) | VAF 89/429 reads (21%) | catalogued as rs1413215652; called by muse, mutect2, varscan2
- KDM5A | c.3576T>A p.P1192= | Silent (SNP) | VAF 99/424 reads (23%) | called by muse, mutect2, varscan2
- KIF1A | c.550C>T p.L184= | Silent (SNP) | VAF 82/418 reads (20%) | called by muse, mutect2, varscan2
- NOM1 | c.1506C>T p.I502= | Silent (SNP) | VAF 58/308 reads (19%) | called by muse, mutect2, varscan2
- OR8H3 | c.891G>A p.V297= | Silent (SNP) | VAF 42/221 reads (19%) | catalogued as rs1419676390, COSV57909095, COSV57910686; called by muse, mutect2, varscan2
- PLPPR3 | c.1200C>T p.D400= (on ENST00000520876 / NM_001270366.2; = p.D428= on NM_024888.2) | Silent (SNP) | VAF 123/700 reads (18%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1695C>T p.L565= | Silent (SNP) | VAF 72/300 reads (24%) | catalogued as COSV58527450; called by muse, mutect2, varscan2
- PRDM14 | c.243T>A p.G81= | Silent (SNP) | VAF 155/685 reads (23%) | called by muse, mutect2, varscan2
- SFTPA1 | c.498G>A p.R166= | Silent (SNP) | VAF 72/453 reads (16%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.1324C>T p.L442= | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as COSV56870307; called by muse, mutect2, varscan2
- SPATA31A3 | c.3276C>T p.N1092= | Silent (SNP) | VAF 162/738 reads (22%) | catalogued as rs1463764199; called by muse, mutect2, varscan2
- TUBA8 | c.834C>T p.A278= | Silent (SNP) | VAF 105/474 reads (22%) | catalogued as rs200912021; called by muse, mutect2, varscan2
- ATP2B2 | c.*2361G>A | 3'UTR (SNP) | VAF 105/472 reads (22%) | catalogued as rs987816299; called by muse, mutect2, varscan2
